Surgical pathology report (de-identified scan), TCGA case TCGA-V5-A7RE, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Duke University, specimen TCGA-V5-A7RE-01A (Primary Tumor).

Results

Surgical Pathology

Result Data

ACCESSION

Entry Date

Component Results

Component

Lab

Clinical History

Esophageal carcinoma.

Gross Examination

Outside case A:

Date of surgery:

Number of slides:

Received from:

Tel:

Fax:

TCG-0-3

Adenocarcinoma NOS 8/40/13

Site: Esophagus, middle third
C15.4

Esophagus NOS C15.9

9/11/14

Outside path report received? Yes

Material to be returned? Yes

Microscopic Examination

Microscopic examination is performed.

Diagnosis

A. OUTSIDE CASE, [REDACTED]. DATE OF
PROCEDURE [REDACTED]:

"ESOPHAGEAL ULCER" (ENDOSCOPIC BIOPSY):

DETACHED FRAGMENTS OF ADENOCARCINOMA WITH AREAS OF ULCERATION.

"ESOPHAGEAL POLYP" (ENDOSCOPIC BIOPSY):

BARRETT'S ESOPHAGUS WITH HIGH GRADE DYSPLASIA.

COMMENT: There is at least pT1a adenocarcinoma (lamina propria invasion) present in the esophageal ulcer biopsy. Definitive submucosal invasion is not seen in this sample, but correlation with endoscopic findings is suggested.

Comment:

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed: [REDACTED]

Testing Performed By

Lab - Name Director Address Valid Date Range

Lab and Collection

MDA Discrepancy		☒
Don't/Synchronous Primary Noted		☒
Reviewer Initials: [REDACTED] Date Reviewed: 9/12/13		

Source: NCI Genomic Data Commons file 123a135f-733c-4ae8-b5ea-5acc18b7d038 (TCGA-V5-A7RE.CA85A8FF-1849-4D46-92F4-51C827E3A419.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).